Somatic mutation profile of tumor specimen TCGA-B8-A54D-01A (aliquot TCGA-B8-A54D-01A-21D-A25V-10) from TCGA case TCGA-B8-A54D, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 69.6 years (25,429 days).
Specimen TCGA-B8-A54D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bc235a7-2606-4454-92a6-a5ac41b6e464.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-A54D-10A (Blood Derived Normal), aliquot TCGA-B8-A54D-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c566ee51-0840-4a95-acb0-b435dd837fea

The open-access MAF lists 61 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 37, Silent 11, Nonsense Mutation 6, Frame Shift Del 3, Splice Site 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN4 | c.2619dup p.D874Rfs*17 | Frame Shift Ins (INS) | VAF 29/95 reads (31%) | catalogued as rs869292397; called by mutect2, pindel, varscan2
- APPL2 | c.860G>C p.R287T | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99314380; called by muse, mutect2, varscan2
- ARAP2 | c.735C>G p.F245L | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs777222577, COSV100393979; called by muse, mutect2, varscan2
- ARMC8 | c.616A>C p.M206L (on ENST00000469044 / NM_001363941.2; = p.M192L on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.71); PolyPhen benign (0.354); catalogued as COSV100627456; called by muse, mutect2, varscan2
- BCAT1 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as COSV53911054; called by muse, varscan2
- BTNL3 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV100732153; called by muse, mutect2
- CASP8AP2 | c.382del p.R128Afs*6 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as COSV52747024; called by mutect2, pindel, varscan2
- CCDC138 | c.1745C>T p.T582I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs761784183, COSV99718660; called by muse, mutect2, varscan2
- CD163L1 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.125); catalogued as COSV100549528; called by muse, varscan2
- CKAP5 | c.3673G>A p.A1225T | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100370273; called by muse, mutect2
- CPEB4 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.421); catalogued as COSV99436573; called by muse, mutect2, varscan2
- DSC3 | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100844388; called by muse, mutect2, varscan2
- FIGN | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 73/277 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs1323683739, COSV100291269; called by muse, mutect2, varscan2
- GPR75 | c.693G>C p.K231N | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as rs1312350718, COSV100765711; called by muse, mutect2
- GTF3C2 | c.1829T>A p.L610Q | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV99272026; called by muse, mutect2, varscan2
- H3C13 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.045); catalogued as rs782255373; called by muse, mutect2
- IL1R1 | c.390G>T p.Q130H | Missense Mutation (SNP) | VAF 78/315 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99292289; called by muse, mutect2, varscan2
- IPO5 | c.233A>C p.Y78S | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.791); catalogued as COSV99846899; called by muse, mutect2, varscan2
- IWS1 | c.1566T>G p.H522Q | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV99766937; called by muse, mutect2, varscan2
- KNL1 | c.1247T>G p.I416S (on ENST00000346991 / NM_170589.5; = p.I390S on NM_144508.5) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as COSV100705775; called by muse, mutect2, varscan2
- LCMT2 | c.2045T>C p.L682S | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV99979869; called by muse, mutect2, varscan2
- LRP2 | c.13811A>G p.E4604G | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV99785966; called by muse, mutect2, varscan2
- MAML1 | c.646C>A p.L216M | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as COSV99482831; called by muse, mutect2, varscan2
- MAPK6 | c.1281C>G p.Y427* | Nonsense Mutation (SNP) | VAF 33/118 reads (28%) | catalogued as COSV99958799; called by muse, mutect2, varscan2
- MARK3 | c.1958C>G p.A653G (on ENST00000429436 / NM_001128918.3; = p.A629G on NM_002376.6) | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.087); catalogued as rs1480796396, COSV99357659; called by muse, mutect2, varscan2
- NELFCD | c.803G>A p.R268H (on ENST00000602795; = p.R250H on NM_198976.4) | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs770356436, COSV59746737; called by muse, mutect2, varscan2
- OR10J3 | c.593T>C p.I198T | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs771118632, COSV100171557; called by muse, mutect2, varscan2
- POTEE | c.2789C>A p.A930E | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); catalogued as COSV58237603; called by muse, mutect2
- PPP1R16B | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 54/192 reads (28%) | catalogued as rs1242087219, COSV100238826; called by muse, mutect2, varscan2
- PPP1R18 | c.1190G>A p.C397Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV99223508; called by muse, mutect2, varscan2
- PRPF6 | c.1431T>G p.N477K | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV99411086; called by muse, mutect2, varscan2
- RAET1L | c.288G>T p.E96D | Missense Mutation (SNP) | VAF 18/688 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99657681; called by muse, mutect2
- ROCK1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101296206; called by muse, mutect2, varscan2
- RYR1 | c.11810C>A p.S3937* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | catalogued as COSV100614124, COSV62104631; called by muse, mutect2, varscan2
- SCLT1 | c.1615A>G p.K539E | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs774139322, COSV99827429; called by muse, mutect2, varscan2
- SH3BGR | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs764009477, COSV100374304; called by muse, mutect2, varscan2
- SYNE1 | c.22509G>C p.E7503D (on ENST00000367255 / NM_182961.4; = p.E7432D on NM_033071.3) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99550237; called by muse, mutect2, varscan2
- TAF1L | c.4526G>T p.R1509L | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV54264485, COSV99643969; called by muse, mutect2, varscan2
- TSPAN31 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.059); catalogued as COSV57275612, COSV99225837; called by muse, mutect2, varscan2
- UNC80 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 30/150 reads (20%) | catalogued as rs538956139, COSV55884499; called by muse, mutect2, varscan2
- UPF2 | c.3796A>C p.K1266Q | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.95); catalogued as COSV100706846; called by muse, mutect2, varscan2
- VEGFC | c.704+2T>G p.X235_splice | Splice Site (SNP) | VAF 14/152 reads (9%) | catalogued as COSV99709289; called by muse, mutect2
- ZC3H12D | c.623C>A p.P208H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101116771; called by mutect2, varscan2
- ZC3HAV1 | c.1037G>T p.S346I | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV99648109; called by muse, mutect2, varscan2
- ARHGAP26 | c.460_463delinsT p.K154_K155delins* | Nonsense Mutation (DEL) | VAF 46/209 reads (22%) | called by pindel, varscan2*
- KRT12 | c.1387+1del p.X463_splice | Splice Site (DEL) | VAF 29/135 reads (21%) | called by mutect2, pindel, varscan2
- PRRC2B | c.95_97del p.V32del | In Frame Del (DEL) | VAF 34/101 reads (34%) | called by mutect2, pindel, varscan2
- SPTA1 | c.3163C>T p.Q1055* | Nonsense Mutation (SNP) | VAF 5/123 reads (4%) | called by muse, mutect2
- TUBGCP6 | c.3346del p.R1116Gfs*208 | Frame Shift Del (DEL) | VAF 56/240 reads (23%) | called by mutect2, pindel, varscan2
- USP29 | c.2509_2510del p.N837Ffs*10 | Frame Shift Del (DEL) | VAF 35/154 reads (23%) | called by mutect2, pindel, varscan2
- ADAMTS19 | c.3387A>T p.G1129= | Silent (SNP) | VAF 90/307 reads (29%) | catalogued as COSV99176186; called by muse, mutect2, varscan2
- FAM171B | c.1917G>A p.E639= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs750763364, COSV100488190; called by muse, mutect2, varscan2
- IRX2 | c.1395G>C p.G465= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as rs748558424, COSV100121533, COSV100121646; called by muse, mutect2, varscan2
- KIAA1217 | c.5649A>G p.Q1883= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as COSV100286019; called by muse, mutect2, varscan2
- LEPR | c.666C>T p.F222= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as COSV100756191; called by muse, mutect2
- LONP1 | c.2445C>G p.R815= | Silent (SNP) | VAF 91/319 reads (29%) | catalogued as COSV100638501; called by muse, mutect2, varscan2
- MSS51 | c.864C>T p.Y288= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as COSV100200063; called by muse, mutect2
- PROP1 | c.57C>T p.S19= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV100383592; called by muse, mutect2, varscan2
- QPCTL | c.1068C>T p.T356= | Silent (SNP) | VAF 91/324 reads (28%) | catalogued as rs368942904; called by muse, mutect2, varscan2
- SLC38A10 | c.3207G>A p.G1069= | Silent (SNP) | VAF 60/201 reads (30%) | catalogued as COSV101042674; called by muse, mutect2, varscan2
- THBS1 | c.1554C>T p.L518= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV99527434; called by muse, mutect2, varscan2
